Somatic mutation profile of tumor specimen TCGA-VD-A8KB-01A (aliquot TCGA-VD-A8KB-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KB, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.8 years (24,393 days).
Specimen TCGA-VD-A8KB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07db34dc-f534-43a7-8e05-5c96aa8defb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KB-10C (Blood Derived Normal), aliquot TCGA-VD-A8KB-10C-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2821cb65-657b-4b7c-982e-b1d7e49990da

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 46/86 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C2orf16 | c.4983_5006del p.S1661_R1668del | In Frame Del (DEL) | VAF 46/192 reads (24%) | catalogued as rs1558459412; called by muse*, mutect2, varscan2*
- DENND3 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs571831372, COSV52801720; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs75669887; called by muse, mutect2, varscan2
- GTDC1 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs115723847; called by muse, mutect2, varscan2
- KRT32 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as rs1361360350; called by muse, mutect2, varscan2
- NCF2 | c.1319A>C p.K440T | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs979540396; called by muse, mutect2, varscan2
- NPEPL1 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1420947341, COSV100622506; called by muse, mutect2, varscan2
- ROS1 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs766232395; called by muse, mutect2, varscan2
- MINAR1 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PITPNM2 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF43 | c.1805A>G p.N602S | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAP130 | c.321G>T p.L107F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- LMO3 | c.117G>A p.K39= | Silent (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- OR6K3 | c.957G>A p.L319= (on ENST00000368146; = p.L303= on NM_001005327.2) | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs927290143; called by muse, mutect2, varscan2
- SCN11A | c.3471G>A p.A1157= | Silent (SNP) | VAF 69/139 reads (50%) | catalogued as rs771153034, COSV100181135; ClinVar: likely benign; called by muse, mutect2, varscan2
- THOC2 | c.2013C>A p.G671= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs1204579479; called by muse, mutect2, varscan2
- TRAF2 | c.1326C>T p.H442= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs560077345, COSV56036868; called by muse, mutect2, varscan2
